Somatic mutation profile of tumor specimen TCGA-BT-A20Q-01A (aliquot TCGA-BT-A20Q-01A-11D-A14W-08) from TCGA case TCGA-BT-A20Q, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Trigone of bladder; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 73.3 years (26,778 days).
Specimen TCGA-BT-A20Q-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4ae51959-0571-4b34-afc4-b774043c12c0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BT-A20Q-11A (Solid Tissue Normal), aliquot TCGA-BT-A20Q-11A-11D-A14W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/33d61c78-da73-4ea9-aa10-ca6ed8f6b775

The open-access MAF lists 104 somatic variants for this specimen: 82 protein-altering or splice-affecting, 20 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 63, Silent 20, Nonsense Mutation 12, Frame Shift Del 3, Frame Shift Ins 2, Splice Site 1, 5'Flank 1, In Frame Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 10/43 reads (23%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ANKAR | c.3190A>G p.I1064V | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as COSV55612834; called by muse, mutect2, varscan2
- ARHGEF26 | c.319C>G p.R107G | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.001); catalogued as COSV62846524; called by muse, mutect2, varscan2
- ARHGEF3 | c.381C>G p.I127M | Missense Mutation (SNP) | VAF 32/121 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV56326682; called by muse, mutect2, varscan2
- ARL13B | c.820G>C p.E274Q (on ENST00000394222 / NM_001174150.2; = p.E167Q on NM_144996.4) | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.044); catalogued as COSV57398337; called by muse, varscan2
- ARMC3 | c.2392C>T p.R798* | Nonsense Mutation (SNP) | VAF 24/72 reads (33%) | catalogued as rs756308547, COSV53066164; called by muse, mutect2, varscan2
- ASAH2 | c.1082G>A p.R361H | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs549196716, COSV61483335; called by muse, mutect2, varscan2
- BMI1 | c.329C>G p.S110C | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.885); catalogued as COSV64959071; called by muse, mutect2, varscan2
- BRWD1 | c.2905C>T p.R969* | Nonsense Mutation (SNP) | VAF 7/43 reads (16%) | catalogued as rs750289132, COSV60892937; called by muse, mutect2
- C4BPA | c.738T>A p.H246Q | Missense Mutation (SNP) | VAF 36/127 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.105); catalogued as COSV65536239, COSV65536407; called by muse, mutect2, varscan2
- CCDC87 | c.1273C>T p.H425Y | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV59579117; called by muse, mutect2, varscan2
- CEP250 | c.214G>C p.E72Q | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); catalogued as COSV61170155; called by muse, varscan2
- CHD9 | c.2686A>G p.I896V | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as COSV54610506; called by muse, mutect2, varscan2
- COL1A1 | c.668C>G p.P223R | Missense Mutation (SNP) | VAF 38/183 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.136); catalogued as COSV56804966; called by muse, mutect2, varscan2
- COL5A2 | c.580C>G p.Q194E | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.68); catalogued as COSV66409863; called by muse, mutect2, varscan2
- CYP26A1 | c.1253G>A p.R418Q | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771590214, COSV56418231; called by muse, mutect2, varscan2
- DDIT4 | c.671C>T p.S224L | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1261060647, COSV100259207, COSV56577503; called by muse, mutect2, varscan2
- DOCK3 | c.4491G>C p.E1497D | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.029); catalogued as COSV56521933; called by muse, mutect2, varscan2
- ELP5 | c.739G>A p.D247N | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV63039445; called by muse, varscan2
- ELP5 | c.784G>C p.E262Q | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV63039355; called by muse, varscan2
- EPN2 | c.1115C>A p.P372H | Missense Mutation (SNP) | VAF 158/468 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.711); catalogued as COSV100127774, COSV59060974; called by muse, mutect2, varscan2
- FAM120A | c.2644C>T p.Q882* | Nonsense Mutation (SNP) | VAF 11/15 reads (73%) | catalogued as COSV99464752; called by muse, mutect2, varscan2
- GPR39 | c.157C>T p.R53W | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.956); catalogued as rs1022860709, COSV61423570; called by muse, mutect2, varscan2
- GTF3C3 | c.1762C>G p.L588V | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.775); catalogued as COSV55832163, COSV99826919; called by muse, mutect2, varscan2
- H3-3A | c.110A>G p.K37R | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); catalogued as COSV64732041, COSV64732785; called by muse, mutect2, varscan2
- HMCN1 | c.14003G>A p.R4668K | Missense Mutation (SNP) | VAF 41/154 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV54894505, COSV54901062; called by muse, mutect2, varscan2
- HTRA3 | c.503G>A p.R168H | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.042); catalogued as rs201529995, COSV56471093; called by muse, mutect2, varscan2
- IFT140 | c.1867G>C p.E623Q | Missense Mutation (SNP) | VAF 60/205 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs1321057610, COSV68488686; called by muse, mutect2, varscan2
- IL17B | c.332G>A p.R111H | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs373011468; called by muse, mutect2, varscan2
- IL2RG | c.82C>G p.L28V | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.111); catalogued as COSV52148439; called by muse, mutect2, varscan2
- KIR3DL1 | c.122G>A p.R41Q | Missense Mutation (SNP) | VAF 43/105 reads (41%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs369021301, COSV58492233; called by muse, mutect2, varscan2
- KMT2A | c.7516G>A p.E2506K | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.395); catalogued as COSV63283826, COSV63285854; called by muse, mutect2, varscan2
- KMT2A | c.8515G>A p.D2839N | Missense Mutation (SNP) | VAF 37/133 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV63285865; called by muse, mutect2, varscan2
- KNOP1 | c.247G>C p.E83Q | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.082); catalogued as rs746730360, COSV54927921; called by muse, mutect2, varscan2
- LPA | c.3968G>A p.C1323Y | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60302051; called by muse, mutect2, varscan2
- METAP1 | c.1105G>C p.E369Q | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as rs748247308, COSV56444049; called by muse, mutect2, varscan2
- MINDY1 | c.265G>C p.E89Q | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.915); catalogued as COSV56498839; called by muse, mutect2, varscan2
- MSANTD4 | c.504A>G p.I168M | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs1265610293, COSV57285843; called by muse, mutect2, varscan2
- MYCBP2 | c.5711C>T p.S1904F (on ENST00000357337; = p.S1942F on NM_015057.5) | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV62019537; called by muse, mutect2, varscan2
- NCOR1 | c.1879C>T p.R627* | Nonsense Mutation (SNP) | VAF 40/85 reads (47%) | catalogued as COSV51984309, COSV51992684, COSV52001655; called by muse, mutect2, varscan2
- NLRP8 | c.752C>T p.T251M | Missense Mutation (SNP) | VAF 39/120 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.053); catalogued as rs764375811, COSV52585164; called by muse, mutect2, varscan2
- OLFML2B | c.1036A>T p.T346S | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as COSV54196522; called by muse, mutect2, varscan2
- OR10A6 | c.647T>C p.L216S | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.969); catalogued as COSV59165141; called by muse, mutect2, varscan2
- POLI | c.1249C>T p.R417* | Nonsense Mutation (SNP) | VAF 11/56 reads (20%) | catalogued as rs56152401, COSV99470989; called by muse, mutect2, varscan2
- PPIE | c.661G>A p.D221N | Missense Mutation (SNP) | VAF 33/67 reads (49%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.806); catalogued as COSV60971697; called by muse, mutect2, varscan2
- PPP1R18 | c.499C>A p.L167M | Missense Mutation (SNP) | VAF 71/207 reads (34%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.201); catalogued as COSV51296007; called by muse, mutect2, varscan2
- PTPN14 | c.2027C>T p.P676L | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as rs202055949, COSV65284122; called by muse, mutect2, varscan2
- PTPN7 | c.392-1G>A p.X131_splice (on ENST00000495688; = p.X170_splice on NM_002832.4 and 3 other RefSeq transcripts) | Splice Site (SNP) | VAF 9/30 reads (30%) | catalogued as COSV58312140, COSV58312868; called by muse, mutect2, varscan2
- RASGEF1A | c.124G>A p.D42N | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.145); catalogued as COSV65666912; called by muse, mutect2, varscan2
- RNF112 | c.1871G>A p.R624Q | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as rs1045207770, COSV71327002; called by muse, mutect2
- RTN1 | c.607G>A p.E203K | Missense Mutation (SNP) | VAF 76/226 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs770735520, COSV50724269; called by muse, mutect2, varscan2
- SLC4A8 | c.1939C>T p.H647Y | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.106); catalogued as COSV60652109; called by muse, mutect2, varscan2
- SMPD1 | c.991C>T p.P331S | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs142476839; called by muse, varscan2
- SNX33 | c.153T>G p.F51L | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as COSV57913540; called by muse, mutect2, varscan2
- SP3 | c.1666G>A p.D556N | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.518); catalogued as COSV59467629; called by muse, mutect2, varscan2
- SYNE1 | c.12034G>A p.G4012S (on ENST00000367255 / NM_182961.4; = p.G3941S on NM_033071.3) | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV54983827; called by mutect2, varscan2
- TCEAL9 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 22/36 reads (61%) | SIFT tolerated (0.34); PolyPhen benign (0.209); catalogued as COSV65488992; called by muse, mutect2, varscan2
- TET2 | c.1397C>G p.S466C | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); catalogued as COSV54411734; called by muse, mutect2, varscan2
- TET2 | c.1526C>G p.S509* | Nonsense Mutation (SNP) | VAF 11/50 reads (22%) | catalogued as rs771408533, COSV54424506; called by muse, mutect2, varscan2
- TFRC | c.880G>A p.E294K | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as COSV64054812; called by muse, mutect2, varscan2
- TPR | c.1939A>G p.T647A | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV66601466; called by muse, mutect2, varscan2
- TSNAX | c.489_493del p.K164Sfs*4 | Frame Shift Del (DEL) | VAF 10/39 reads (26%) | catalogued as rs768705359; called by mutect2, pindel, varscan2
- TTN | c.7657G>C p.E2553Q (on ENST00000591111; = p.E2507Q on NM_003319.4) | Missense Mutation (SNP) | VAF 20/56 reads (36%) | PolyPhen benign (0.369); catalogued as COSV60066571, COSV60407123; called by muse, mutect2, varscan2
- UBTF | c.932A>C p.E311A | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV57186162; called by muse, mutect2, varscan2
- UFSP2 | c.712C>A p.H238N | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV52991591; called by muse, mutect2, varscan2
- VPS13D | c.10178A>T p.D3393V | Missense Mutation (SNP) | VAF 75/228 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); catalogued as COSV50639381; called by muse, mutect2, varscan2
- ZNF777 | c.2251G>A p.A751T | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.066); catalogued as rs758027729, COSV56097683; called by muse, mutect2, varscan2
- ANGPT2 | c.711_745del p.T238* | Frame Shift Del (DEL) | VAF 26/110 reads (24%) | called by mutect2, pindel
- ARID1A | c.3513_3516del p.S1171Rfs*8 | Frame Shift Del (DEL) | VAF 10/39 reads (26%) | called by mutect2, pindel, varscan2
- BEST1 | c.973A>G p.M325V | Missense Mutation (SNP) | VAF 2/9 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.874); called by muse, mutect2
- CPE | c.1150C>T p.Q384* | Nonsense Mutation (SNP) | VAF 16/55 reads (29%) | called by muse, mutect2, varscan2
- CSMD1 | c.1540C>T p.P514S (on ENST00000520002; = p.P513S on NM_033225.6) | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.75); PolyPhen benign (0.026); called by muse, mutect2
- ECPAS | c.3209T>G p.L1070R | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ELF3 | c.582dup p.D195* | Frame Shift Ins (INS) | VAF 13/44 reads (30%) | called by mutect2, pindel, varscan2
- H4C13 | c.175_177del p.L59del | In Frame Del (DEL) | VAF 10/47 reads (21%) | called by mutect2, pindel, varscan2
- IFIH1 | c.11_12dup p.Y5Gfs*19 | Frame Shift Ins (INS) | VAF 16/77 reads (21%) | called by mutect2, pindel, varscan2
- IQGAP3 | c.3806C>G p.S1269* | Nonsense Mutation (SNP) | VAF 29/79 reads (37%) | called by muse, mutect2, varscan2
- KANSL1 | c.2993C>G p.S998* (on ENST00000574590 / NM_001193465.2; = p.S999* on NM_015443.4) | Nonsense Mutation (SNP) | VAF 11/69 reads (16%) | called by mutect2, varscan2
- MISP | c.2016C>G p.I672M | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- SNRPB2 | c.413C>G p.S138* | Nonsense Mutation (SNP) | VAF 10/35 reads (29%) | called by muse, mutect2, varscan2
- TNFSF4 | c.94C>T p.Q32* | Nonsense Mutation (SNP) | VAF 15/54 reads (28%) | called by muse, mutect2, varscan2
- ZNF573 | c.1868C>G p.S623* (on ENST00000536220 / NM_001172692.1; = p.S565* on NM_152360.3) | Nonsense Mutation (SNP) | VAF 47/128 reads (37%) | called by muse, mutect2, varscan2
- CDC14A | c.540C>T p.F180= | Silent (SNP) | VAF 29/74 reads (39%) | catalogued as COSV60558519; called by muse, mutect2, varscan2
- CPPED1 | c.894G>C p.L298= | Silent (SNP) | VAF 29/77 reads (38%) | catalogued as COSV55496238, COSV55497373; called by muse, mutect2, varscan2
- CRHR2 | c.213C>G p.V71= | Silent (SNP) | VAF 13/33 reads (39%) | catalogued as COSV59265393; called by muse, mutect2, varscan2
- CYP2E1 | c.1134C>T p.F378= | Silent (SNP) | VAF 21/52 reads (40%) | catalogued as COSV53313398; called by muse, mutect2, varscan2
- ELAVL1 | c.204C>T p.Y68= | Silent (SNP) | VAF 15/64 reads (23%) | catalogued as rs767301210, COSV60966596; called by muse, mutect2, varscan2
- GGCX | c.432G>A p.L144= | Silent (SNP) | VAF 25/70 reads (36%) | catalogued as COSV52088357; called by muse, mutect2, varscan2
- GNAZ | c.1011C>T p.F337= | Silent (SNP) | VAF 14/31 reads (45%) | catalogued as rs139659965; called by muse, mutect2, varscan2
- HPR | c.438C>G p.L146= | Silent (SNP) | VAF 13/45 reads (29%) | catalogued as COSV57182728; called by muse, mutect2, varscan2
- MAB21L3 | c.798G>A p.L266= | Silent (SNP) | VAF 4/31 reads (13%) | called by muse, mutect2
- MRPS17 | c.171G>A p.Q57= | Silent (SNP) | VAF 96/327 reads (29%) | catalogued as COSV53392400; called by muse, mutect2, varscan2
- PSEN2 | c.255G>A p.A85= | Silent (SNP) | VAF 20/75 reads (27%) | catalogued as rs765023751, COSV60916269; called by muse, mutect2, varscan2
- PUS7L | c.1962A>G p.Q654= | Silent (SNP) | VAF 38/141 reads (27%) | catalogued as rs765660293, COSV61261885; called by muse, mutect2, varscan2
- RAPGEF2 | c.1420C>T p.L474= | Silent (SNP) | VAF 20/66 reads (30%) | catalogued as COSV52428254; called by muse, mutect2, varscan2
- RNF5 | c.454C>T p.L152= | Silent (SNP) | VAF 93/287 reads (32%) | catalogued as COSV61247643; called by muse, mutect2, varscan2
- SNX22 | c.465G>C p.S155= | Silent (SNP) | VAF 20/135 reads (15%) | catalogued as COSV55520234; called by muse, mutect2, varscan2
- TBXAS1 | c.417G>A p.L139= | Silent (SNP) | VAF 76/228 reads (33%) | catalogued as COSV54945438; called by muse, mutect2, varscan2
- TEDC2 | c.189C>T p.P63= | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as rs751969814, COSV53539991; called by muse, mutect2, varscan2
- TRPM4 | c.3240C>T p.I1080= | Silent (SNP) | VAF 22/55 reads (40%) | catalogued as COSV53262846; called by muse, mutect2, varscan2
- UBR4 | c.11037G>A p.E3679= | Silent (SNP) | VAF 18/55 reads (33%) | catalogued as COSV64389794; called by muse, mutect2, varscan2
- ZNF516 | c.2466C>T p.L822= | Silent (SNP) | VAF 32/110 reads (29%) | catalogued as rs763906125, COSV71587026; called by muse, mutect2, varscan2
- PPP3R1 | chr2:68253082 G>A | 5'Flank (SNP) | VAF 13/26 reads (50%) | catalogued as COSV99310444; called by muse, mutect2, varscan2
- SNORD115-30 | n.61C>T | RNA (SNP) | VAF 76/248 reads (31%) | called by muse, mutect2, varscan2
